Somatic mutation profile of tumor specimen TCGA-VP-A87D-01A (aliquot TCGA-VP-A87D-01A-11D-A34U-08) from TCGA case TCGA-VP-A87D, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.3 years (19,818 days).
Specimen TCGA-VP-A87D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273b6b02-234e-47f2-b164-c1b066ef9a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87D-10A (Blood Derived Normal), aliquot TCGA-VP-A87D-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d081063b-c7a4-4ab2-86d4-7bb060ce8372

The open-access MAF lists 52 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA2 | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as rs200288072, CS102090, CS151377, COSV70354805; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.257_279del p.A86Vfs*55 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs886041861; ClinVar: pathogenic; called by mutect2, varscan2
- ADAD2 | c.1387G>A p.A463T (on ENST00000315906 / NM_001145400.2; = p.A545T on NM_139174.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951758185, COSV51892554; called by muse, mutect2, varscan2
- ADAMTS10 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as rs782607385, COSV99546309; ClinVar: uncertain significance; called by muse, mutect2
- BCAN | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as rs749412358, COSV100227796; called by muse, mutect2
- CACNA1E | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100701155; called by muse, mutect2, varscan2
- CCDC71 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1198108804, COSV100422261; called by muse, mutect2, varscan2
- CCSAP | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs747189562, COSV99497223; called by muse, mutect2, varscan2
- CD207 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs370350846; called by muse, mutect2, varscan2
- COL11A1 | c.1052A>G p.Q351R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs751155680, COSV100614460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.1237A>C p.T413P | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99852322; called by muse, mutect2, varscan2
- CREB3L4 | c.715_717del p.K239del | In Frame Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs749320152; called by pindel, varscan2
- DSCAML1 | c.4235C>G p.A1412G (on ENST00000321322; = p.A1352G on NM_020693.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV100354187; called by muse, mutect2, varscan2
- ELN | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV99332072; called by muse, varscan2
- ETV5 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60501449; called by muse, mutect2, varscan2
- H2BC17 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.639); catalogued as COSV100377417, COSV58153254; called by muse, mutect2
- HACD3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs769410818, COSV99970880; called by muse, mutect2, varscan2
- HDAC3 | c.893A>C p.Y298S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539358, COSV59496854; called by muse, mutect2, varscan2
- HDGFL2 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV100012041; called by muse, mutect2, varscan2
- KCNK10 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs975831463, COSV100066997; called by muse, mutect2, varscan2
- KIF13A | c.3872G>A p.R1291K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV52449366; called by muse, mutect2, varscan2
- MAP2K7 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101208947; called by muse, mutect2
- MUC17 | c.4846G>A p.A1616T | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs768113808, COSV60293970; called by muse, mutect2, varscan2
- MYLK | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV100658351, COSV60612191; called by muse, mutect2
- MYO16 | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV62748184; called by muse, mutect2, varscan2
- OR5M8 | c.879T>G p.N293K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV100510504; called by muse, mutect2, varscan2
- OR5M8 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59116460; called by muse, mutect2, varscan2
- PCDH11Y | c.592C>T p.P198S (on ENST00000400457 / NM_032973.2; = p.P187S on NM_032971.3) | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99290253; called by muse, mutect2, varscan2
- PCDHA12 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.421); catalogued as COSV100246930; called by muse, mutect2
- PHF2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.693); catalogued as rs756410471, COSV63678999; called by muse, mutect2, varscan2
- PIGH | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99372935; called by muse, mutect2, varscan2
- PLPPR5 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54171364, COSV99586843; called by muse, mutect2, varscan2
- PPEF2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99713999; called by muse, mutect2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- RETSAT | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs151321935; called by muse, mutect2, varscan2
- SLC12A6 | c.2983G>T p.E995* (on ENST00000354181 / NM_001365088.1; = p.E944* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV51622090, COSV99270705; called by muse, mutect2, varscan2
- TMEM199 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV99134649; called by muse, mutect2, varscan2
- UTRN | c.9923C>T p.T3308M | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs755338194, COSV100838087; called by muse, mutect2
- ZC3H13 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs528381815, COSV54464994; called by muse, mutect2, varscan2
- ZNF184 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99279331; called by muse, mutect2
- ZNF256 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.334); catalogued as COSV99990537; called by muse, mutect2, varscan2
- PRAMEF20 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 124/321 reads (39%) | called by muse, mutect2, varscan2
- SENP7 | c.852_861del p.K284Nfs*11 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel
- FAM47C | c.1677C>T p.R559= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV100792231; called by muse, mutect2, varscan2
- OSBPL6 | c.141C>T p.T47= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs139099797; called by muse, mutect2, varscan2
- PARVB | c.669G>A p.S223= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs747721118, COSV100114408, COSV100115097; called by muse, mutect2, varscan2
- SLC9C2 | c.2352T>C p.A784= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100876507; called by muse, mutect2, varscan2
- TIAM2 | c.2685G>A p.K895= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV100017736, COSV59696081; called by muse, mutect2, varscan2
- TTC30A | c.1599T>C p.Y533= | Silent (SNP) | VAF 105/292 reads (36%) | catalogued as rs775029939, COSV100826117; called by muse, mutect2, varscan2
- ZNF93 | c.1362G>A p.K454= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs145106089; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3170T>A | Intron (SNP) | VAF 41/127 reads (32%) | catalogued as COSV100093118; called by muse, mutect2, varscan2
- NECTIN2 | c.1043-3629G>A | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99374716; called by muse, mutect2
